Gene-level copy-number profile of tumor specimen TCGA-HV-A7OL-01A from TCGA case TCGA-HV-A7OL, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 70.5 years (25,768 days).
Specimen TCGA-HV-A7OL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.2d069417-12dd-4122-8574-655133fa48fc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HV-A7OL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/88ec7301-0fff-4413-9e7d-8b3b4a0dc10d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 8,819; copy number 2: 48,866; copy number 3: 1,865; copy number 4: 78; copy number 5: 86; copy number 7: 21; copy number 9: 71.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HV-A7OL-01A-11D-A33S-01): tumor purity 0.39, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:50,795,120–51,643,939, 14 genes (within-gene range 0–1): MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 178 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–2,069,089, 77 genes, copy number 5–9 (broad region; genes not listed).
- chr4:2,088,718–2,141,058, 2 genes, copy number 5: AL136360.1, AL136360.2.
- chr4:3,889,356–7,742,836, 78 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:19,215,615–19,336,715, 1 gene, copy number 7 (within-gene range 1–7): EPN2.
- chr17:19,296,596–19,597,922, 20 genes, copy number 7 (within-gene range 3–7): EPN2-AS1, B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, AC004448.5, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2.

Autosomal genes at a single copy (total copy number 1): 6,432. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
